Gene-level copy-number profile of tumor specimen C3L-01696-54 from CPTAC case C3L-01696, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 62.2 years (22,728 days).
Specimen C3L-01696-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 75da9806-dab5-4c5c-b296-e93c89fcb4f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01696-51 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,719 have no estimate.
https://portal.gdc.cancer.gov/files/4ebd2ef0-d090-4928-89fe-2ea6b2d875e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,168; copy number 1: 6,447; copy number 2: 42,341; copy number 3: 5,164; copy number 4: 899; copy number 5: 703; copy number 6: 487; copy number 7: 288; copy number 8: 155; copy number 9: 108; copy number 10: 41; copy number 11: 19; copy number 12: 13; copy number 13: 8; copy number 14: 7; copy number 15: 13; copy number 16: 3; copy number 17: 2; copy number 18: 4; copy number 19: 2; copy number 20: 6; copy number 22: 3; copy number 25: 1; copy number 27: 2; copy number 28: 3; copy number 29: 3; copy number 32: 2; copy number 33: 1; copy number 35: 1; copy number 36: 3; copy number 37: 1; copy number 39: 1; copy number 40: 2; copy number 52: 1; copy number 260: 1; copy number 402: 1.

Homozygous deletions (total copy number 0; autosomes only): 1,044 genes in 574 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,534,449–37,566,857, 4 genes (within-gene range 0–1): SNIP1, FTH1P1, AL034379.1, DNALI1.
- chr1:89,181,144–89,272,804, 4 genes: GBP4, AC099063.4, GBP5, AC099063.1.
- chr1:115,270,767–115,368,072, 4 genes: AL049825.1, NGF-AS1, NGF, AL512638.3.
- chr2:91,686,102–91,843,802, 8 genes: AC027612.2, NKAIN1P2, AC027612.1, KMT5AP2, AC027612.3, GGT8P, IGKV1OR2-1, ABCD1P5.
- chr2:95,574,901–95,641,980, 11 genes: TRIM51JP, AC009237.16, AC009237.4, TRIM43, AC009237.7, AC009237.13, AC009237.12, UBTFL3, AC009237.17, AC009237.6, AC009237.9.
- chr2:178,521,183–178,830,802, 10 genes (within-gene range 0–2): TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1.
- chr3:49,857,988–49,916,937, 6 genes (within-gene range 0–2): CAMKV, RN7SL217P, ACTBP13, MST1R, AC105935.2, AC105935.1.
- chr3:52,316,319–52,535,054, 9 genes (within-gene range 0–5): DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2.
- chr5:98,213,402–98,411,792, 6 genes: PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24.
- chr5:98,679,402–98,833,711, 5 genes (within-gene range 0–12): DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3.
- chr6:27,865,317–27,893,891, 7 genes (within-gene range 0–6): H2AC16, H1-5, H3C11, H4C13, H3C12, H2AC17, H2BC17.
- chr6:30,005,971–30,070,333, 8 genes (within-gene range 0–5): HLA-J, AL671277.2, ETF1P1, AL669914.3, AL669914.2, POLR1H, AL669914.4, PPP1R11.
- chr6:33,314,406–33,366,243, 5 genes: ZBTB22, DAXX, SMIM40, SMIM40, LYPLA2P1.
- chr6:132,722,787–132,817,564, 9 genes: VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33.
- chr9:128,504,719–128,633,662, 6 genes (within-gene range 0–2): GLE1, AL356481.1, RNU7-171P, SPTAN1, AL356481.2, AL356481.3.
- chr10:58,269,162–58,370,751, 4 genes: CISD1, AC016396.1, AC016396.2, UBE2D1.
- chr10:118,692,361–119,029,544, 4 genes (within-gene range 0–4): AL139407.1, AL157388.1, RPL17P36, LDHAP5.
- chr11:64,206,678–64,249,494, 11 genes: FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2.
- chr11:66,509,079–66,546,235, 4 genes (within-gene range 0–1): AP002748.5, BBS1, AP002748.6, ZDHHC24.
- chr11:118,133,377–118,225,094, 4 genes: SCN4B, SCN2B, JAML, HSPE1P18.
- chr12:57,472,264–57,547,224, 8 genes (within-gene range 0–2): ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2.
- chr12:57,723,761–57,756,013, 5 genes (within-gene range 0–24): AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759.
- chr12:57,762,334–57,797,554, 4 genes (within-gene range 0–1): CYP27B1, METTL1, EEF1AKMT3, AC025165.3.
- chr12:123,602,077–123,662,604, 6 genes: DDX55, SNORA9B, EIF2B1, GTF2H3, AC117503.3, AC117503.2.
- chr12:123,707,602–123,761,755, 5 genes (within-gene range 0–45): AC117503.1, ATP6V0A2, AC117503.5, RPL27P12, AC117503.4.
- chr14:39,174,885–39,216,335, 4 genes: AL132639.3, PNN, AL132639.1, YTHDF2P1.
- chr15:25,085,385–25,097,754, 10 genes (within-gene range 0–2): SNORD116-18, SNORD116-19, AC124312.3, SNORD116-20, SNORD116-21, SNORD116-22, SNORD116-23, AC124312.4, SNORD116-24, SNORD116-25.
- chr15:25,169,337–25,176,913, 5 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4.
- chr15:25,184,306–25,189,495, 4 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11.
- chr15:25,199,448–25,206,343, 5 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20.
- chr15:28,378,621–28,426,584, 6 genes: GOLGA8F, RN7SL238P, ABCB10P3, AC091304.8, AC091304.5, MIR4509-2.
- chr15:42,942,897–43,221,018, 5 genes (within-gene range 0–3): UBR1, AC068724.2, RPS3AP47, SPCS2P1, EPB42.
- chr15:43,593,054–43,632,283, 4 genes (within-gene range 0–9): CKMT1B, STRC, RNU6-554P, AC011330.3.
- chr15:43,702,363–43,799,133, 6 genes (within-gene range 0–1): RNU6-353P, CATSPER2P1, RNU6-354P, PDIA3, ELL3, AC018512.1.
- chr15:48,331,011–48,663,056, 6 genes (within-gene range 0–4): DUT, FBN1, AC022467.2, AC022467.1, AC084757.3, AC084757.4.
- chr15:69,391,192–69,448,427, 5 genes (within-gene range 0–5): AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1.
- chr15:75,737,820–75,786,898, 6 genes (within-gene range 0–14): AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1, RN7SL319P.
- chr17:10,383,132–10,698,375, 11 genes (within-gene range 0–5): AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2.
- chr18:22,169,589–22,228,029, 5 genes (within-gene range 0–8): GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2.
- chr19:52,113,091–52,171,643, 5 genes (within-gene range 0–7): ZNF616, AC011468.2, AC011468.3, RPL37P23, ZNF836.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,787 genes in 806 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,059,615–3,438,621, 8 genes, copy number 7–12 (within-gene range 7–18): PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1.
- chr1:4,654,609–5,668,295, 7 genes, copy number 5–10: AJAP1, Z98886.1, LINC02782, Z98259.3, Z98259.1, AL365255.1, Z97988.1.
- chr1:36,466,043–37,325,100, 7 genes, copy number 5–10: CSF3R, FTLP18, AC117945.1, AL353604.1, MIR4255, RNU6-636P, RNA5SP43.
- chr1:213,492,288–214,041,510, 7 genes, copy number 5–6 (within-gene range 5–7): AL592402.1, AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1.
- chr1:235,519,971–235,650,754, 8 genes, copy number 5–36: MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, GNG4, FO393422.1, AL583844.1.
- chr2:34,692,290–35,725,142, 9 genes, copy number 5–7 (within-gene range 5–8): AC073218.1, AC012593.2, AC012593.1, RN7SL602P, AC019064.1, MIR548AD, RNU6-1117P, AC083939.1, MRPL50P1.
- chr2:150,169,474–151,048,774, 9 genes, copy number 5–7: LINC01818, LINC01817, RND3, LINC01920, AC104777.2, AC104777.1, LINC02612, AC023469.2, AC023469.1.
- chr2:202,614,214–202,769,757, 9 genes, copy number 5–6: MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B.
- chr2:236,153,071–236,369,102, 6 genes, copy number 5–7 (within-gene range 0–8): Y_RNA, GBX2, AC019068.1, ASB18, RNU1-31P, AC093915.1.
- chr3:147,844,123–148,127,233, 6 genes, copy number 5–7: AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2.
- chr4:39,528,019–39,666,879, 6 genes, copy number 5–6 (within-gene range 2–7): UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2.
- chr4:53,986,587–54,087,783, 7 genes, copy number 5–10: RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1.
- chr5:17,367,588–17,620,939, 24 genes, copy number 5–7: AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20.
- chr5:166,128,498–168,264,157, 14 genes, copy number 5–8 (within-gene range 0–8): AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1.
- chr6:28,033,947–28,139,678, 10 genes, copy number 6–9: OR2W2P, OR2B7P, OR2B8P, OR1F12, AL121944.1, ZNF165, ZSCAN12P1, ZNF602P, ZSCAN16, AL358933.1.
- chr6:168,716,606–169,182,841, 8 genes, copy number 5–9: AL136099.1, AL513210.2, AL513210.1, AL109924.3, AL109924.1, AL109924.2, LINC01615, LINC02544.
- chr7:46,634,614–47,079,128, 7 genes, copy number 5–8 (within-gene range 1–8): HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4.
- chr7:130,853,720–131,110,176, 7 genes, copy number 5–8 (within-gene range 2–8): LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT.
- chr8:20,246,165–21,298,168, 12 genes, copy number 5–8 (within-gene range 3–8): LZTS1, LZTS1-AS1, RNA5SP257, AC023403.1, AC022559.1, AC018541.1, TMEM97P2, AC015468.3, AC021613.1, AC015468.1, AC015468.2, LINC02153.
- chr9:22,646,200–23,672,399, 7 genes, copy number 5–6: LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1.
- chr9:117,462,294–118,083,382, 9 genes, copy number 5–6: AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9.
- chr10:4,497,449–4,891,975, 6 genes, copy number 5–6: AC022535.2, RNU6-163P, MANCR, LINC00705, AKR1E2, AKR1C6P.
- chr10:78,179,174–79,067,895, 10 genes, copy number 6–9 (within-gene range 6–14): AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1.
- chr10:112,446,998–112,832,454, 7 genes, copy number 7–9 (within-gene range 7–11): VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4.
- chr11:126,423,358–127,003,460, 8 genes, copy number 6–9 (within-gene range 1–9): KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2.
- chr12:116,482,073–116,698,065, 6 genes, copy number 5–10: LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2.
- chr12:127,274,265–127,619,447, 9 genes, copy number 5–9: LINC02376, AC073913.1, RNU1-104P, LINC02375, AC073913.2, AC048347.1, AC068787.1, AC025252.1, Y_RNA.
- chr12:128,187,225–128,707,915, 6 genes, copy number 6 (within-gene range 6–9): AC061709.2, TMEM132C, AC061709.3, MIR3612, AC023595.1, AC090424.1.
- chr12:130,121,925–130,266,725, 7 genes, copy number 6–260: AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10, AC026336.1, AC026336.2.
- chr12:132,084,283–132,585,188, 25 genes, copy number 6–9 (within-gene range 4–9): EP400P1, AC138466.5, AC138466.2, DDX51, NOC4L, AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2.
- chr13:96,090,839–96,984,172, 8 genes, copy number 5–6: HS6ST3, RN7SL164P, MIR4501, AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7.
- chr15:28,473,322–28,533,014, 6 genes, copy number 9–11: AC138749.4, MIR4509-3, AC138749.7, ABCB10P4, GOLGA8G, Metazoa_SRP.
- chr15:97,982,509–98,420,998, 10 genes, copy number 5–9 (within-gene range 4–22): AC024651.1, LINC02251, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351.
- chr17:61,034,636–61,400,243, 7 genes, copy number 5–9 (within-gene range 0–20): AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1.
- chr18:5,081,171–5,238,598, 6 genes, copy number 5–6 (within-gene range 2–6): LINC01892, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526.
- chr18:21,673,628–21,831,539, 8 genes, copy number 5–18 (within-gene range 2–18): AC106037.3, MIR320C1, AC106037.1, Y_RNA, RN7SL233P, MIR133A1HG, MIR133A1, MIR1-2.
- chr19:27,638,483–28,727,777, 26 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1.
- chr19:28,869,507–29,617,237, 19 genes, copy number 5–10: AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4.
- chr20:47,656,348–48,477,553, 16 genes, copy number 5–10 (within-gene range 2–10): SULF2, AL354813.1, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2.
- chr20:61,077,224–61,940,617, 6 genes, copy number 6 (within-gene range 2–7): AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1.

Autosomal genes at a single copy (total copy number 1): 5,944. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
